Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A3SG, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A3SG-01A (Primary Tumor).

- LAB RESULTS

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:
1) RIGHT THYROID (LOBECTOMY):

SPECIMEN TYPE:
Right lobectomy

HISTOLOGIC TYPE:
Papillary carcinoma

TUMOR SIZE:
3.2 cm greatest dimension

FOCALITY:
Multifocal

LYMPH NODES:
Metastatic carcinoma in 6 of 14 lymph nodes
See part 3

EXTENT OF INVASION
PRIMARY TUMOR:
pT2: Tumor >2 cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:
pN1b: Metastasis to cervical or mediastinal nodes

DISTANT METASTASIS:
pMx: Cannot be assessed

MARGINS:
Margins are uninvolved
Distance of invasive carcinoma from
nearest margin: <1 mm (anterior, lateral)

VENOUS/LYMPHATIC INVASION:
Absent

ADDITIONAL PATHOLOGIC FINDINGS:
None identified

2) LEFT THYROID (LOBECTOMY): HISTOLOGICALLY UNREMARKABLE THYROID,
NEGATIVE FOR TUMOR. FOUR OF FOUR (4/4) LYMPH NODES NEGATIVE FOR
TUMOR. PARATHYROID TISSUE IDENTIFIED.

3) LYMPH NODE, CENTRAL COMPARTMENT (DISSECTION): METASTATIC
PAPILLARY CARCINOMA IN FIVE OF NINE (5/9) LYMPH NODES. THYMIC TISSUE
IDENTIFIED. PARATHYROID TISSUE IDENTIFIED.

Reported by:

Final Report Signed on

ICD-O-3
Carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS
C73.9 5-1-12
R0

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
UNLESS OTHERWISE NOTED ON THE REPORT PAGE, ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file 24a3d3ce-e0f0-47f7-af2a-c67d7c6e39cc (TCGA-FK-A3SG.7BF00F56-23C5-4B17-B890-71D1E7AF1B7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).